Somatic mutation profile of tumor specimen TCGA-QA-A7B7-01A (aliquot TCGA-QA-A7B7-01A-11D-A32G-10) from TCGA case TCGA-QA-A7B7, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 48.3 years (17,636 days).
Specimen TCGA-QA-A7B7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b236d96a-9a31-462f-881f-35eeac01139b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QA-A7B7-10A (Blood Derived Normal), aliquot TCGA-QA-A7B7-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69e6145a-c48f-4109-8d2e-fca7cf4c665b

The open-access MAF lists 97 somatic variants for this specimen: 69 protein-altering or splice-affecting, 26 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 26, Nonsense Mutation 4, Intron 2, In Frame Del 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 35/46 reads (76%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- ABRA | c.167C>A p.T56N | Missense Mutation (SNP) | VAF 96/118 reads (81%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV61733688; called by muse, varscan2
- AICDA | c.86T>G p.L29R | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57564330, COSV57566414; called by muse, mutect2, varscan2
- ATP13A4 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55075498; called by muse, mutect2, varscan2
- BTAF1 | c.2178G>T p.R726S | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56439666; called by muse, mutect2, varscan2
- C1RL | c.1343A>G p.H448R | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV56926806; called by muse, mutect2, varscan2
- CACNA2D4 | c.3349G>C p.A1117P | Missense Mutation (SNP) | VAF 53/132 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as CD142900, COSV54961276; called by muse, mutect2, varscan2
- CADM2 | c.403C>A p.P135T (on ENST00000407528 / NM_001167674.2; = p.P137T on NM_153184.4) | Missense Mutation (SNP) | VAF 83/234 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV67405680; called by muse, mutect2, varscan2
- CHIC2 | c.206A>G p.N69S | Missense Mutation (SNP) | VAF 85/197 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs374480856; called by muse, mutect2, varscan2
- CNR1 | c.382A>T p.T128S | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.554); catalogued as COSV62986674; called by muse, varscan2
- COL5A1 | c.4645G>A p.G1549S | Missense Mutation (SNP) | VAF 46/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65672680; called by muse, mutect2, varscan2
- CRYBG2 | c.4324G>A p.E1442K | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV57490399; called by muse, mutect2, varscan2
- CTNND2 | c.2131G>A p.V711M | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV58929738; called by muse, mutect2, varscan2
- CUL2 | c.545A>G p.H182R | Missense Mutation (SNP) | VAF 126/188 reads (67%) | SIFT tolerated (0.8); PolyPhen benign (0.023); catalogued as rs1564718050, COSV66081209; called by muse, mutect2, varscan2
- DNAH7 | c.11474G>A p.S3825N | Missense Mutation (SNP) | VAF 124/304 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV56787535; called by muse, mutect2, varscan2
- EI24 | c.676A>T p.I226F | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.42); catalogued as COSV54021286; called by muse, mutect2, varscan2
- EPHA3 | c.1256G>T p.S419I | Missense Mutation (SNP) | VAF 37/78 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs1282140504, COSV60693711, COSV60728342; called by muse, mutect2, varscan2
- ERCC6L | c.2303T>C p.I768T | Missense Mutation (SNP) | VAF 94/108 reads (87%) | SIFT deleterious (0.04); PolyPhen benign (0.236); catalogued as rs1428388180, COSV57822442; called by muse, mutect2, varscan2
- ESYT2 | c.1790G>A p.R597H (on ENST00000613624; = p.R521H on NM_020728.3) | Missense Mutation (SNP) | VAF 50/62 reads (81%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs755282073, COSV51749333; called by muse, mutect2, varscan2
- EVA1C | c.1024G>T p.V342F | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV55827049; called by muse, mutect2, varscan2
- FASLG | c.205C>G p.P69A | Missense Mutation (SNP) | VAF 128/222 reads (58%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV100390300; called by muse, varscan2
- FASLG | c.206C>A p.P69Q | Missense Mutation (SNP) | VAF 130/224 reads (58%) | SIFT tolerated (0.41); PolyPhen benign (0.022); catalogued as COSV100390293, COSV100390302; called by muse, varscan2
- GALNT5 | c.1127T>C p.V376A | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1410081999, COSV52041452, COSV99374752; called by muse, mutect2, varscan2
- GPR152 | c.964C>G p.P322A | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.287); catalogued as COSV56888249; called by muse, mutect2, varscan2
- GPR35 | c.615C>A p.D205E | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.31); PolyPhen benign (0.057); catalogued as COSV60578723; called by muse, mutect2, varscan2
- GRIA3 | c.1336G>T p.E446* | Nonsense Mutation (SNP) | VAF 90/109 reads (83%) | catalogued as COSV52056297, COSV52081133; called by muse, varscan2
- GRIP1 | c.1624C>T p.Q542* (on ENST00000359742 / NM_001379345.1; = p.Q490* on NM_021150.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 67/174 reads (39%) | catalogued as COSV54044085; called by muse, mutect2, varscan2
- GRM1 | c.1643C>A p.T548K | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM113014, COSV51130099, COSV51357849; called by muse, mutect2, varscan2
- HEATR1 | c.5245G>A p.E1749K | Missense Mutation (SNP) | VAF 60/191 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); catalogued as rs745546689, COSV100857794, COSV63981564; called by muse, mutect2, varscan2
- HMCN1 | c.6494A>G p.Q2165R | Missense Mutation (SNP) | VAF 26/124 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV54943221; called by muse, mutect2, varscan2
- HR | c.359G>C p.G120A | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.138); catalogued as COSV57194792; called by muse, mutect2, varscan2
- HRNR | c.6109G>A p.G2037S | Missense Mutation (SNP) | VAF 55/309 reads (18%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.539); catalogued as rs753847125, COSV64263151; called by muse, mutect2, varscan2
- IPO9 | c.1907T>C p.I636T | Missense Mutation (SNP) | VAF 60/108 reads (56%) | SIFT tolerated (0.7); PolyPhen benign (0.078); catalogued as rs776235060, COSV64236308; called by muse, varscan2
- IQCE | c.2020G>A p.V674I | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs760012088, COSV58082115; called by muse, mutect2, varscan2
- KLHL14 | c.1735A>G p.S579G | Missense Mutation (SNP) | VAF 59/136 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV63835641; called by muse, mutect2, varscan2
- LCT | c.2881G>A p.A961T | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV51557765; called by muse, mutect2, varscan2
- LOX | c.850T>A p.Y284N | Missense Mutation (SNP) | VAF 85/210 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV50241443; called by muse, mutect2, varscan2
- LRP3 | c.487C>T p.Q163* | Nonsense Mutation (SNP) | VAF 19/37 reads (51%) | catalogued as COSV53507614; called by muse, mutect2, varscan2
- LRRC4B | c.1292C>T p.T431M | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV65350315; called by muse, mutect2, varscan2
- MTSS2 | c.1777G>A p.V593M | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV55382640; called by muse, mutect2, varscan2
- MYO1E | c.1417G>T p.V473L | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.314); catalogued as COSV55695619; called by muse, mutect2, varscan2
- NCOA7 | c.463C>A p.L155I | Missense Mutation (SNP) | VAF 89/215 reads (41%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV57660530; called by muse, mutect2, varscan2
- NDNF | c.530C>A p.P177H | Missense Mutation (SNP) | VAF 85/186 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65634154; called by muse, mutect2, varscan2
- NEB | c.8388A>C p.E2796D | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV51461187; called by muse, mutect2, varscan2
- OR14A16 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 100/148 reads (68%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); catalogued as COSV62927523; called by muse, mutect2, varscan2
- PCDHGA12 | c.1119C>A p.D373E | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52768996; called by muse, mutect2, varscan2
- PCSK9 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV53778996; called by muse, mutect2, varscan2
- PELI3 | c.974C>A p.A325E | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV57857884; called by muse, mutect2, varscan2
- PLCB1 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.219); catalogued as rs150241349; ClinVar: likely benign; called by muse, mutect2, varscan2
- PNLIP | c.644T>C p.F215S | Missense Mutation (SNP) | VAF 47/67 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65042037; called by muse, mutect2, varscan2
- PNMA2 | c.530A>T p.E177V | Missense Mutation (SNP) | VAF 34/42 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV72908615; called by muse, mutect2, varscan2
- PTEN | c.878del p.G293Efs*14 | Frame Shift Del (DEL) | VAF 63/106 reads (59%) | catalogued as COSV64306603; called by mutect2, pindel, varscan2
- RABGGTA | c.1661A>T p.Q554L | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV52865605; called by muse, mutect2, varscan2
- RAI14 | c.355G>T p.G119W | Missense Mutation (SNP) | VAF 88/204 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54303853; called by muse, varscan2
- SETX | c.5548A>G p.M1850V | Missense Mutation (SNP) | VAF 64/169 reads (38%) | SIFT tolerated (0.51); PolyPhen benign (0.017); catalogued as COSV56395089; called by muse, mutect2, varscan2
- SH3RF3 | c.1266C>G p.D422E | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58695822; called by muse, mutect2, varscan2
- SIRPB1 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs139432093, COSV53540865; called by muse, mutect2, varscan2
- SPATA17 | c.515A>T p.K172M | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV65126315; called by muse, mutect2, varscan2
- SPTBN1 | c.3659C>T p.A1220V | Missense Mutation (SNP) | VAF 46/121 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as COSV61694417; called by muse, mutect2, varscan2
- TENT4A | c.830C>G p.P277R | Missense Mutation (SNP) | VAF 102/263 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50101974; called by muse, mutect2, varscan2
- THBS2 | c.1122C>A p.C374* | Nonsense Mutation (SNP) | VAF 14/31 reads (45%) | catalogued as COSV64682298; called by muse, mutect2, varscan2
- TMPRSS11D | c.905C>A p.P302H | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.683); catalogued as COSV52226373; called by muse, mutect2, varscan2
- VN1R4 | c.854T>C p.L285P | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60805719; called by muse, mutect2, varscan2
- WNT6 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 41/93 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0.062); catalogued as COSV52111231; called by muse, mutect2, varscan2
- ZNF638 | c.5500G>A p.V1834I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV52497376; called by muse, mutect2, varscan2
- ZNF708 | c.1213T>G p.S405A | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.487); catalogued as COSV63608896; called by muse, mutect2, varscan2
- ADAMTS12 | c.298_300del p.K100del | In Frame Del (DEL) | VAF 47/102 reads (46%) | called by mutect2, pindel, varscan2
- C3 | c.730_732del p.Y244del | In Frame Del (DEL) | VAF 16/36 reads (44%) | called by pindel, varscan2
- TRIM49 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.011); called by mutect2, varscan2
- AGL | c.2580T>C p.V860= | Silent (SNP) | VAF 65/178 reads (37%) | catalogued as COSV54059055; called by muse, mutect2, varscan2
- AHCTF1 | c.3270C>A p.I1090= (on ENST00000366508; = p.I1064= on NM_015446.5) | Silent (SNP) | VAF 201/355 reads (57%) | catalogued as COSV58255982; called by muse, mutect2, varscan2
- CACNA1B | c.1350C>T p.R450= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as rs201843778; called by muse, mutect2, varscan2
- CAPN13 | c.69C>A p.T23= | Silent (SNP) | VAF 60/146 reads (41%) | catalogued as COSV54435597, COSV99700246; called by muse, mutect2, varscan2
- CCDC136 | c.1632A>G p.T544= | Silent (SNP) | VAF 89/107 reads (83%) | catalogued as COSV52805219; called by muse, mutect2, varscan2
- CCDC63 | c.1200C>T p.Y400= | Silent (SNP) | VAF 36/71 reads (51%) | catalogued as rs141258896; called by muse, mutect2, varscan2
- CHGA | c.549C>G p.T183= | Silent (SNP) | VAF 12/14 reads (86%) | catalogued as COSV53664136, COSV53664673; called by muse, mutect2, varscan2
- DCAF5 | c.2568G>A p.V856= | Silent (SNP) | VAF 29/90 reads (32%) | catalogued as COSV58463293; called by muse, mutect2, varscan2
- DZIP3 | c.3495C>T p.C1165= | Silent (SNP) | VAF 87/238 reads (37%) | catalogued as rs200425501; called by muse, mutect2, varscan2
- EFCAB7 | c.435C>T p.A145= | Silent (SNP) | VAF 115/299 reads (38%) | catalogued as COSV64315418; called by muse, mutect2, varscan2
- FAM234A | c.876C>T p.L292= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV56998464; called by muse, mutect2, varscan2
- GARRE1 | c.2700C>T p.H900= | Silent (SNP) | VAF 35/72 reads (49%) | catalogued as rs150651317; called by muse, mutect2, varscan2
- GRIA3 | c.1335G>T p.L445= | Silent (SNP) | VAF 86/106 reads (81%) | catalogued as COSV52081108, COSV99991194; called by muse, varscan2
- H3C2 | c.63G>T p.L21= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV52520010; called by muse, mutect2, varscan2
- HERC1 | c.6184T>C p.L2062= | Silent (SNP) | VAF 64/116 reads (55%) | catalogued as COSV71250356; called by muse, mutect2, varscan2
- IGHMBP2 | c.1428A>T p.P476= | Silent (SNP) | VAF 35/60 reads (58%) | catalogued as COSV54826431; called by muse, mutect2, varscan2
- INTS5 | c.2352T>A p.V784= | Silent (SNP) | VAF 57/130 reads (44%) | catalogued as COSV57953704; called by muse, mutect2, varscan2
- KCNQ5 | c.75G>T p.A25= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV59683717; called by muse, mutect2, varscan2
- MAN1A2 | c.1881A>G p.L627= | Silent (SNP) | VAF 42/75 reads (56%) | catalogued as rs757179136, COSV62981778; called by muse, mutect2, varscan2
- MMEL1 | c.1929C>T p.H643= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as COSV56526427, COSV99984315; called by muse, mutect2, varscan2
- PGR | c.804C>G p.V268= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs186653307, COSV54811087; called by muse, mutect2, varscan2
- SELENOF | c.39G>T p.V13= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV59357353; called by muse, mutect2, varscan2
- SHANK1 | c.5313C>A p.G1771= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as COSV53262813; called by muse, mutect2, varscan2
- SLC35B1 | c.252G>A p.E84= (on ENST00000649906; = p.E47= on NM_005827.4) | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as COSV53604341; called by muse, mutect2, varscan2
- UGGT2 | c.1983A>G p.T661= | Silent (SNP) | VAF 82/187 reads (44%) | catalogued as rs773423460, COSV65079709; called by muse, mutect2, varscan2
- ZG16B | c.183C>T p.G61= | Silent (SNP) | VAF 23/115 reads (20%) | catalogued as COSV66526353; called by muse, mutect2, varscan2
- PDE9A | c.219-1481C>T | Intron (SNP) | VAF 64/236 reads (27%) | catalogued as COSV52331687; called by muse, mutect2, varscan2
- TTN | c.10361-5169G>A | Intron (SNP) | VAF 94/215 reads (44%) | catalogued as COSV60360978; called by muse, mutect2
